Somatic mutation profile of tumor specimen TCGA-XN-A8T3-01A (aliquot TCGA-XN-A8T3-01A-11D-A36O-08) from TCGA case TCGA-XN-A8T3, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.9 years (24,810 days).
Specimen TCGA-XN-A8T3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d9d9db2-106f-41b3-bef3-1c0ceed20806.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XN-A8T3-10A (Blood Derived Normal), aliquot TCGA-XN-A8T3-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/727e8d13-6bf4-43ac-92e5-66823068d616

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6445C>T p.R2149* | Nonsense Mutation (SNP) | VAF 52/414 reads (13%) | catalogued as rs61750654, CM990078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 92/440 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 17/113 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHRR | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs751406178, COSV57084475; called by muse, mutect2, varscan2
- BTAF1 | c.5262G>T p.L1754F | Missense Mutation (SNP) | VAF 73/489 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99795367; called by muse, mutect2, varscan2
- C8orf34 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 45/615 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs548341726, COSV57416688; called by muse, mutect2
- DCP1B | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV54966917, COSV99767531; called by muse, mutect2, varscan2
- DNAJB14 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 44/508 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100508477; called by muse, mutect2
- FASTK | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs377740282; called by muse, mutect2, varscan2
- HTR2A | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs376305063; called by muse, mutect2, varscan2
- IGLV2-11 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 134/1706 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.5); catalogued as rs546965481; called by muse, mutect2
- NLGN1 | c.1988G>A p.S663N | Missense Mutation (SNP) | VAF 37/517 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100849385; called by muse, mutect2
- NT5C1B | c.538C>A p.P180T (on ENST00000359846 / NM_001199086.2; = p.P120T on NM_033253.4) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100410043; called by muse, mutect2
- OBSCN | c.3223G>T p.A1075S | Missense Mutation (SNP) | VAF 46/559 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as COSV99478444; called by muse, mutect2
- OR2M2 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 182/1075 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs149761766; called by muse, mutect2, varscan2
- PDZRN3 | c.2789C>T p.T930M | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs745814121, COSV55195914, COSV55209287; called by muse, mutect2, varscan2
- PRDM5 | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 75/619 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53363456; called by muse, mutect2, varscan2
- PROZ | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751897530, COSV100720344; called by muse, mutect2, varscan2
- RIMS2 | c.4123G>A p.V1375M (on ENST00000666250 / NM_001348490.2; = p.V946M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/794 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs377163259; called by muse, mutect2, varscan2
- RNF38 | c.1504A>G p.I502V | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs200434728, COSV99425082; called by muse, mutect2, varscan2
- SGCG | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 196/1112 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs886042216, COSV99522964; ClinVar: uncertain significance; called by muse, varscan2
- SSUH2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs377451237; called by muse, mutect2, varscan2
- STAT1 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs770809861, COSV100738650; called by muse, mutect2
- STS | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 52/337 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.528); catalogued as COSV54266813; called by muse, mutect2, varscan2
- TNXB | c.4336C>T p.R1446W (on ENST00000647633; = p.R1199W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1462486516, COSV100926341; called by muse, mutect2, varscan2
- TRIM38 | c.557T>G p.L186R | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100837582; called by muse, mutect2
- TTN | c.23764G>A p.A7922T (on ENST00000591111; = p.A6995T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/343 reads (15%) | PolyPhen benign (0.143); catalogued as COSV100613907; called by muse, mutect2, varscan2
- TUBA8 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100283128; called by muse, mutect2
- ZFP91 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 34/332 reads (10%) | catalogued as COSV60157197; called by muse, mutect2
- ZNF772 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 44/601 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs771011227, COSV100582836; called by muse, mutect2
- AMER3 | c.1669del p.A557Rfs*127 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- IGKV1D-42 | c.341T>A p.F114Y | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAQR9 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF10L | c.1611G>A p.L537= | Silent (SNP) | VAF 94/615 reads (15%) | catalogued as COSV99392938; called by muse, mutect2, varscan2
- ATP7B | c.549C>T p.A183= | Silent (SNP) | VAF 43/289 reads (15%) | catalogued as rs772619981, COSV99666466; ClinVar: likely benign; called by muse, mutect2, varscan2
- CMYA5 | c.810G>A p.E270= | Silent (SNP) | VAF 20/311 reads (6%) | catalogued as COSV71406261; called by muse, mutect2
- CRNN | c.219A>G p.E73= | Silent (SNP) | VAF 27/482 reads (6%) | catalogued as rs767589261, COSV99664138; called by muse, mutect2
- CSF2RB | c.1719G>A p.P573= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs140662059; called by muse, mutect2, varscan2
- DIMT1 | c.99G>T p.G33= | Silent (SNP) | VAF 72/507 reads (14%) | catalogued as rs751850541, COSV52234143, COSV99551113; called by muse, mutect2, varscan2
- LUZP4 | c.429G>A p.P143= | Silent (SNP) | VAF 38/213 reads (18%) | catalogued as rs148942179, COSV64219062; called by muse, mutect2, varscan2
- OR2T4 | c.9C>T p.N3= | Silent (SNP) | VAF 44/357 reads (12%) | catalogued as rs200949727, COSV100822452; called by muse, mutect2, varscan2
- RITA1 | c.81C>T p.V27= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV100013898; called by muse, mutect2, varscan2
- ZNF280A | c.1440G>A p.P480= | Silent (SNP) | VAF 59/630 reads (9%) | catalogued as rs765568927, COSV100131061; called by muse, mutect2
- FAM183BP | n.1245C>T | RNA (SNP) | VAF 270/986 reads (27%) | catalogued as rs373142679; called by muse, mutect2, varscan2
